Somatic mutation profile of tumor specimen TCGA-BP-4987-01A (aliquot TCGA-BP-4987-01A-01D-1462-08) from TCGA case TCGA-BP-4987, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 41.2 years (15,041 days).
Specimen TCGA-BP-4987-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24c376be-16f4-47c2-9bf8-f6c6ef00598d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4987-11A (Solid Tissue Normal), aliquot TCGA-BP-4987-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a19749b-8487-41d9-bd9a-9a3dbd30d1b6

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 2, In Frame Del 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as COSV53742873; called by muse, mutect2
- ATP7B | c.1852A>G p.I618V | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV54438195; called by muse, mutect2
- B3GALNT2 | c.223A>T p.M75L | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58356340; called by muse, mutect2
- CSMD3 | c.10781G>T p.G3594V (on ENST00000297405 / NM_001363185.1; = p.G3425V on NM_052900.3) | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52173581; called by muse, mutect2, varscan2
- DAXX | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs775804750, COSV56469131; called by muse, mutect2
- DEFB123 | c.87T>A p.Y29* | Nonsense Mutation (SNP) | VAF 27/230 reads (12%) | catalogued as COSV66233123; called by muse, mutect2, varscan2
- GBP6 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs754452653, COSV65011111, COSV65011471; called by muse, mutect2, varscan2
- GRID2 | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445827888, COSV56202763; called by muse, mutect2, varscan2
- IFNA8 | c.311T>A p.L104H | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66504577; called by muse, mutect2, varscan2
- IGHM | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); catalogued as rs781965773; called by muse, mutect2, varscan2
- INPPL1 | c.228_230del p.E76del | In Frame Del (DEL) | VAF 24/88 reads (27%) | catalogued as rs755318996; called by pindel, varscan2
- MED12 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.566); catalogued as COSV61339312; called by muse, mutect2, varscan2
- PCDHA3 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63541199; called by muse, mutect2
- PKD1L1 | c.4516C>G p.Q1506E | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.437); catalogued as rs908276020, COSV56964334; called by muse, mutect2, varscan2
- PPARGC1A | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 55/425 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53527364, COSV99337904; called by muse, mutect2, varscan2
- SHROOM4 | c.2395A>T p.T799S | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.058); catalogued as COSV56788931; called by muse, mutect2, varscan2
- SPAST | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV59514343; called by muse, mutect2, varscan2
- STAP2 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.66); catalogued as COSV55696019; called by muse, mutect2, varscan2
- CLK2 | c.40_45del p.S14_R15del | In Frame Del (DEL) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
- JAK1 | c.2164del p.L722Wfs*49 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- RIC8B | c.1310_1314del p.D437Afs*27 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.4134A>G p.Q1378= | Silent (SNP) | VAF 134/459 reads (29%) | catalogued as rs202178297, COSV61465599; called by muse, mutect2, varscan2
- INPP4A | c.1137G>A p.L379= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV50791523; called by muse, mutect2
- ITGB3 | c.1944G>C p.R648= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV71383973; called by muse, mutect2, varscan2
- PPP2R2B | c.240C>T p.F80= (on ENST00000394409; = p.F146= on NM_181674.2) | Silent (SNP) | VAF 92/308 reads (30%) | catalogued as rs778750788, COSV60755168; called by muse, mutect2, varscan2
- RPGRIP1 | c.687C>T p.S229= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV52849658; called by muse, mutect2, varscan2
- RYR1 | c.6423G>A p.A2141= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs748805324, COSV62087552, COSV62096605; called by muse, mutect2, varscan2
- SYNE2 | c.1677G>A p.Q559= | Silent (SNP) | VAF 70/226 reads (31%) | catalogued as rs774937188, COSV59950182; called by muse, varscan2
- DIAPH2 | c.3241+39956T>G | Intron (SNP) | VAF 6/140 reads (4%) | catalogued as COSV100234987; called by muse, mutect2
